Somatic mutation profile of tumor specimen MBCProject_6682_T2_WES (aliquot MBCProject_6682_T2_WES_1) from CMI case MBCProject_6682, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.7 years (19,255 days).
Specimen MBCProject_6682_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b18b13f7-ece3-4f75-8c35-cdf9bea6b90a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6682_SALIVA (Saliva), aliquot MBCProject_6682_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5c9472d-9cf1-4a8e-b6f0-8e96ab8996b5

The open-access MAF lists 82 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 10, Intron 9, RNA 5, 3'Flank 2, 5'Flank 2, 3'UTR 2, 5'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 44/128 reads (34%) | catalogued as rs748687137, COSV99921414; called by muse, mutect2, varscan2
- CATSPERG | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99286508; called by muse, mutect2, varscan2
- COL1A1 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs139593707, COSV56810864; called by muse, varscan2
- COL6A1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201213605, COSV62613526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACR2A | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99364623; called by muse, mutect2, varscan2
- CWC15 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1349536602; called by muse, mutect2, varscan2
- DDR2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63373542; called by muse, mutect2, varscan2
- EFCAB1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs751867551; called by muse, mutect2, varscan2
- EVPLL | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs753734836; called by muse, mutect2, varscan2
- FASTK | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs781616427, COSV99879832; called by mutect2, varscan2
- HABP2 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100668118; called by muse, mutect2, varscan2
- IMPDH1 | c.1282C>T p.R428* (on ENST00000470772 / NM_001142573.2; = p.R514* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | catalogued as rs1343867350; called by muse, mutect2, varscan2
- MARCO | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs1377674781; called by muse, mutect2, varscan2
- PYGL | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV99368281; called by muse, mutect2, varscan2
- TAS2R43 | c.875C>A p.S292* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV67855074; called by muse, varscan2
- TMEM106A | c.429G>A p.T143= | Splice Region (SNP) | VAF 6/64 reads (9%) | catalogued as rs1348508801; called by muse, mutect2
- TRPM3 | c.3474G>A p.M1158I (on ENST00000357533 / NM_001366142.2; = p.M1013I on NM_020952.6) | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751123094; called by muse, mutect2, varscan2
- WIPI2 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1562400749; called by muse, mutect2, varscan2
- ZFAT | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1280380201; called by muse, mutect2, varscan2
- ZNF264 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs115405411, COSV99567267; called by muse, mutect2, varscan2
- ABCC8 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ATRAID | c.177C>G p.H59Q (on ENST00000611786; = p.H4Q on NM_001170795.3) | Missense Mutation (SNP) | VAF 96/398 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CEP152 | c.1321+2T>C p.X441_splice | Splice Site (SNP) | VAF 25/384 reads (7%) | called by muse, mutect2
- CGGBP1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, varscan2
- DMWD | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); called by muse, mutect2
- EEFSEC | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ERCC6L2 | c.3115G>C p.D1039H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- EYA4 | c.1802A>G p.K601R (on ENST00000531901 / NM_001301013.1; = p.K595R on NM_004100.5) | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGHV1-18 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- LONP2 | c.1945C>A p.Q649K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAGEB18 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAST4 | c.7162G>T p.E2388* (on ENST00000403625 / NM_001164664.2; = p.E2199* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- MED23 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 123/247 reads (50%) | called by muse, mutect2, varscan2
- MLXIPL | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MYH1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- MYO18A | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MYPN | c.1819A>C p.K607Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PCDHGA8 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- PIP4K2B | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- PYCR3 | c.539del p.G180Afs*79 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- RERGL | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST6GAL2 | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 30/74 reads (41%) | PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- STAG2 | c.1154_1156del p.D385del | In Frame Del (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- TMEM132C | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMEM132C | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- TTBK1 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR33 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF311 | c.1020dup p.K341Qfs*22 | Frame Shift Ins (INS) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- ZNF572 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.2439C>G p.L813= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- FBN2 | c.7518C>T p.C2506= | Silent (SNP) | VAF 182/441 reads (41%) | called by muse, mutect2, varscan2
- HDAC9 | c.672G>A p.L224= | Silent (SNP) | VAF 69/400 reads (17%) | called by muse, mutect2, varscan2
- NTS | c.444G>A p.L148= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, varscan2
- NUP93 | c.192C>T p.L64= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs750501091; called by muse, mutect2, varscan2
- OR13C2 | c.753C>T p.F251= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV73377631; called by muse, mutect2, varscan2
- P2RY8 | c.975C>G p.L325= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV67176784; called by muse, varscan2
- PRSS56 | c.495G>A p.R165= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- SH2D3A | c.1032C>T p.V344= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- SLC12A3 | c.1626C>T p.L542= | Silent (SNP) | VAF 50/228 reads (22%) | catalogued as rs1250940421; called by muse, varscan2
- TMC5 | c.1800C>T p.L600= (on ENST00000396229 / NM_001105248.1; = p.L354= on NM_024780.5) | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- AC104472.1 | n.238T>C | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2
- ALMS1P1 | n.814G>T | RNA (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1891+351C>T | Intron (SNP) | VAF 8/183 reads (4%) | catalogued as rs1015797717, COSV61710218; called by muse, mutect2
- ARX | c.*25C>T | 3'UTR (SNP) | VAF 58/90 reads (64%) | catalogued as rs750074228; called by muse, mutect2, varscan2
- C5 | c.2563-2177A>G | Intron (SNP) | VAF 6/76 reads (8%) | catalogued as rs1351664110; called by muse, mutect2
- CENATAC | chr11:118997127 G>A | 5'Flank (SNP) | VAF 59/182 reads (32%) | called by muse, varscan2
- CPLANE2 | chr1:16229036 A>G | 3'Flank (SNP) | VAF 6/61 reads (10%) | called by muse, varscan2
- EBAG9 | c.522-955G>C | Intron (SNP) | VAF 49/195 reads (25%) | catalogued as rs1419499694; called by muse, mutect2, varscan2
- EIF4H | c.469+902G>A | Intron (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- FOLH1B | n.1921G>T | RNA (SNP) | VAF 20/94 reads (21%) | catalogued as rs1239577984; called by muse, mutect2, varscan2
- GRIK2 | c.952-54960T>C | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- HRG | c.*10C>T | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- KATNAL2 | c.1212-1044dup | Intron (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- LINC02108 | n.192C>T | RNA (SNP) | VAF 8/50 reads (16%) | catalogued as rs1290376422; called by muse, varscan2
- MAGED2 | c.1208+22G>A | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as rs200028230; called by mutect2, varscan2
- NFU1 | chr2:69437463 G>A | 5'Flank (SNP) | VAF 211/611 reads (35%) | catalogued as rs775615702; called by muse, mutect2, varscan2
- NT5E | c.-5C>T | 5'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- NUDT7 | c.348+676C>T | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as rs781463254; called by muse, mutect2, varscan2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 6/31 reads (19%) | catalogued as rs1356395055; called by muse, mutect2
- SNORD113-9 | n.6C>T | RNA (SNP) | VAF 30/98 reads (31%) | called by muse, varscan2
- ZNF235 | c.-30C>T | 5'UTR (SNP) | VAF 62/230 reads (27%) | catalogued as COSV99349800; called by muse, varscan2
- ZNF90 | chr19:20121323 T>C | 3'Flank (SNP) | VAF 10/74 reads (14%) | catalogued as rs1555706533; called by muse, varscan2
